Somatic mutation profile of tumor specimen C3L-03377-02 (aliquot CPT0239770006) from CPTAC case C3L-03377, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.0 years (26,673 days).
Specimen C3L-03377-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff6c6b0d-f763-4b84-81c3-2551cdb16589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03377-31 (Blood Derived Normal), aliquot CPT0240520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2fec2e2-6068-4359-8e3d-9e378beff26e

The open-access MAF lists 810 somatic variants for this specimen: 515 protein-altering or splice-affecting, 261 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 460, Silent 261, Nonsense Mutation 42, Intron 17, Splice Region 6, 5'UTR 6, Splice Site 4, 5'Flank 4, 3'UTR 3, In Frame Del 2, RNA 2, 3'Flank 2.

Variants (750 of 810; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRIP1 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 145/421 reads (34%) | catalogued as rs368796923, COSV99369486; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.7135C>T p.R2379* | Nonsense Mutation (SNP) | VAF 82/140 reads (59%) | catalogued as rs387907275, CM127144, COSV63285436; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 138/394 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 240/509 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1445084199; called by muse, mutect2, varscan2
- ABCC8 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 144/389 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV56854973; called by muse, mutect2, varscan2
- ABCD2 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58051188; called by muse, mutect2, varscan2
- ABI2 | c.715C>T p.R239* (on ENST00000295851 / NM_001375719.1; = p.R233* on NM_005759.7 and 35 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 80/206 reads (39%) | catalogued as rs765445473; called by muse, mutect2, varscan2
- ADAM18 | c.2189T>C p.V730A | Missense Mutation (SNP) | VAF 173/407 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs746413411; called by muse, mutect2, varscan2
- ADAMTS14 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 98/285 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750734959; called by muse, mutect2, varscan2
- ADAMTS19 | c.2995G>A p.G999R | Missense Mutation (SNP) | VAF 131/345 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs867102437; called by muse, mutect2, varscan2
- ADGRV1 | c.8005G>A p.E2669K | Missense Mutation (SNP) | VAF 124/363 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757776405, COSV67983237; called by muse, mutect2, varscan2
- AGBL3 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 320/409 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263808127; called by muse, mutect2, varscan2
- AHSG | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 146/367 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV56608080; called by muse, mutect2, varscan2
- ANXA5 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56639747; called by muse, mutect2, varscan2
- ARGFX | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 158/391 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1346510220; called by muse, mutect2, varscan2
- ARHGEF15 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 248/345 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs752135781, COSV62724730; called by muse, mutect2, varscan2
- ARHGEF40 | c.2509C>T p.Q837* | Nonsense Mutation (SNP) | VAF 133/344 reads (39%) | catalogued as COSV100070087; called by muse, mutect2, varscan2
- ARMCX3 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 159/424 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57871723; called by muse, mutect2, varscan2
- ATP7B | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 127/357 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs1388603839; called by muse, mutect2, varscan2
- BANK1 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59837750; called by muse, mutect2, varscan2
- BBS2 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 121/243 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs147397090; called by muse, mutect2, varscan2
- BCL9 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 135/501 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs782700431; called by muse, mutect2, varscan2
- BCL9 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 170/681 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs369834661; called by muse, mutect2, varscan2
- BCR | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 237/426 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59928467; called by muse, mutect2, varscan2
- C10orf71 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 161/402 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV60510865; called by muse, mutect2, varscan2
- C12orf42 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as rs773446119, COSV59378762; called by muse, mutect2, varscan2
- CA7 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 199/465 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.383); catalogued as rs764520768; called by muse, mutect2, varscan2
- CACNA1C | c.3610C>T p.P1204S | Missense Mutation (SNP) | VAF 129/230 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100222135; called by muse, mutect2, varscan2
- CACNA1E | c.1959C>T p.I653= | Splice Region (SNP) | VAF 174/280 reads (62%) | catalogued as rs757203952, COSV62415427; called by muse, mutect2, varscan2
- CACNA1I | c.4205A>G p.N1402S | Missense Mutation (SNP) | VAF 120/419 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1165484176; called by muse, mutect2, varscan2
- CAPN6 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 167/417 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749267304; called by muse, mutect2, varscan2
- CAPN9 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202096741, COSV55239322; called by muse, mutect2, varscan2
- CBFA2T2 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 146/368 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs148795225; called by muse, mutect2, varscan2
- CBL | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 53/79 reads (67%) | catalogued as CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; called by muse, mutect2, varscan2
- CBL | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 56/82 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1245863855, COSV50657369, COSV50665310; called by muse, mutect2, varscan2
- CBLB | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.007); catalogued as rs1311016924, COSV51425317; called by muse, mutect2, varscan2
- CBLC | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 190/499 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs751438592, COSV54322336; called by muse, mutect2, varscan2
- CCDC144A | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 119/323 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs867830732; called by muse, mutect2, varscan2
- CCDC18 | c.4114G>A p.E1372K | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as rs761981245; called by muse, mutect2, varscan2
- CCDC60 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 146/434 reads (34%) | catalogued as rs773157440; called by muse, mutect2, varscan2
- CCT8L2 | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 127/472 reads (27%) | catalogued as COSV63463603; called by muse, mutect2, varscan2
- CDCA7 | c.482G>A p.R161K (on ENST00000347703 / NM_145810.3; = p.R240K on NM_031942.5) | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as rs1267714326, COSV60719937; called by muse, varscan2
- CDX4 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs758968054, COSV65171481; called by muse, mutect2, varscan2
- CEACAM5 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 183/451 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs782351981; called by muse, mutect2, varscan2
- CELSR2 | c.7724C>T p.T2575M | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1260028332; called by muse, mutect2, varscan2
- CELSR3 | c.5548G>A p.D1850N | Missense Mutation (SNP) | VAF 167/458 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.913); catalogued as rs146491964; called by muse, mutect2, varscan2
- CEP250 | c.3133C>T p.R1045* | Nonsense Mutation (SNP) | VAF 142/337 reads (42%) | catalogued as rs775811770; called by muse, mutect2, varscan2
- CERT1 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); catalogued as rs1248221222; called by muse, mutect2, varscan2
- CFAP58 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 263/464 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371540971, COSV63833041; called by muse, mutect2, varscan2
- CFHR4 | c.1591G>A p.G531R (on ENST00000367416 / NM_001201551.2; = p.G285R on NM_006684.5) | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.482); catalogued as COSV52226308; called by muse, mutect2, varscan2
- CILP | c.3103C>T p.R1035* | Nonsense Mutation (SNP) | VAF 186/306 reads (61%) | catalogued as rs771794833, COSV56026156; called by muse, mutect2, varscan2
- CLEC14A | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV60561694; called by muse, varscan2
- CLEC3A | c.518G>A p.R173Q (on ENST00000651443; = p.R164Q on NM_005752.6) | Missense Mutation (SNP) | VAF 165/503 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs753496661, COSV100222264; called by muse, mutect2, varscan2
- CNBD1 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 125/281 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs866739698, COSV101582132; called by muse, mutect2, varscan2
- CNTNAP5 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs576933313, COSV70474495, COSV70480585; called by muse, mutect2, varscan2
- COL18A1 | c.2962C>T p.P988S (on ENST00000359759 / NM_130444.3; = p.P753S on NM_030582.4) | Missense Mutation (SNP) | VAF 126/338 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1399595323; called by muse, mutect2, varscan2
- COL21A1 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779255; called by muse, mutect2, varscan2
- COL4A4 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs754398956, COSV61630234, COSV61630282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A5 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 153/353 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60359835; called by muse, mutect2, varscan2
- COL4A6 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 214/520 reads (41%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as rs1311288972; called by muse, mutect2, varscan2
- COL7A1 | c.5608C>T p.R1870C | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs145782204; called by muse, mutect2, varscan2
- CREBBP | c.6854C>T p.P2285L | Missense Mutation (SNP) | VAF 262/506 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV52142281; called by muse, mutect2, varscan2
- CSMD1 | c.5470G>A p.G1824R (on ENST00000520002; = p.G1823R on NM_033225.6) | Missense Mutation (SNP) | VAF 123/252 reads (49%) | SIFT tolerated (0.51); PolyPhen probably damaging (1); catalogued as rs751051632, COSV59279459, COSV59374324; called by muse, varscan2
- CSNKA2IP | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs935252709, COSV68072668; called by muse, mutect2, varscan2
- CYP2A7 | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs540089737; called by mutect2, varscan2
- DGKZ | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 186/467 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1435903357, COSV58994036; called by muse, mutect2, varscan2
- DHRS9 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 172/471 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1300215416; called by muse, mutect2, varscan2
- DMD | c.6814G>A p.E2272K | Missense Mutation (SNP) | VAF 163/593 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.061); catalogued as rs1557010214, COSV58926370, COSV58957184; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMD | c.5662G>A p.D1888N | Missense Mutation (SNP) | VAF 324/618 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as CD0910042, COSV63754234; called by muse, mutect2, varscan2
- DNAH10 | c.6966G>A p.W2322* (on ENST00000409039; = p.W2261* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 75/228 reads (33%) | catalogued as COSV68994176; called by muse, mutect2, varscan2
- DNAH14 | c.7957G>A p.E2653K (on ENST00000445597; = p.E3456K on NM_001367479.1) | Missense Mutation (SNP) | VAF 183/273 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as COSV59898531; called by muse, mutect2, varscan2
- DNAH2 | c.1180T>A p.C394S | Missense Mutation (SNP) | VAF 143/205 reads (70%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs750177327; called by muse, mutect2, varscan2
- DNAH3 | c.3329G>A p.G1110E | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54540883, COSV99766181; called by muse, mutect2, varscan2
- DNAH5 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 145/403 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1234602973; called by muse, mutect2, varscan2
- DOCK11 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 101/321 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99352545; called by muse, mutect2, varscan2
- DPYD | c.2841G>A p.M947I | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV64608807; called by muse, mutect2, varscan2
- DRD5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 155/396 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256349931, COSV58577786; called by muse, mutect2, varscan2
- EHHADH | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as rs1001762073; called by muse, mutect2, varscan2
- ERC2 | c.2698C>T p.Q900* | Nonsense Mutation (SNP) | VAF 104/295 reads (35%) | catalogued as COSV99883366; called by muse, mutect2, varscan2
- ESX1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 251/674 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as rs782551355; called by muse, mutect2, varscan2
- FAM71E2 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 138/387 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs188444775; called by muse, mutect2, varscan2
- FANCD2 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 55/333 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as COSV99812008; called by muse, mutect2, varscan2
- FBN3 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 142/398 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs769706501; called by muse, mutect2, varscan2
- FES | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as rs1440426532; called by muse, mutect2, varscan2
- FGL2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 340/436 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV50383276; called by muse, mutect2, varscan2
- FLG2 | c.6878G>A p.R2293K | Missense Mutation (SNP) | VAF 162/704 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as COSV66171162; called by muse, mutect2, varscan2
- FRMD3 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 286/392 reads (73%) | SIFT tolerated (0.29); PolyPhen benign (0.281); catalogued as COSV100170999; called by muse, mutect2, varscan2
- FRMD7 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 208/558 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV53745435; called by muse, mutect2, varscan2
- GABRR2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.347); catalogued as rs868426079; called by muse, mutect2, varscan2
- GABRR3 | c.869G>A p.W290* | Nonsense Mutation (SNP) | VAF 112/329 reads (34%) | catalogued as COSV72084364; called by muse, mutect2, varscan2
- GC | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56735876; called by muse, varscan2
- GIMAP5 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 153/485 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs373678856; called by muse, mutect2, varscan2
- GIMAP7 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 119/163 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as rs201757172; called by muse, mutect2, varscan2
- GLIS3 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 115/191 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1443505574, COSV60930947; called by muse, mutect2, varscan2
- GPLD1 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 120/307 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs778066407, COSV57756505; called by muse, mutect2, varscan2
- GPRASP2 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 135/398 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774126365, COSV59991215; called by muse, mutect2, varscan2
- GRTP1 | c.921+8G>A | Splice Region (SNP) | VAF 171/486 reads (35%) | catalogued as COSV58149747; called by muse, mutect2, varscan2
- GYS1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 144/358 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748140171, COSV54401180; called by muse, mutect2, varscan2
- HBB | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 137/444 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as CM952452; called by muse, mutect2, varscan2
- HDGFL1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 185/494 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57753377; called by muse, mutect2, varscan2
- HEATR9 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 696/1011 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs1380913920; called by muse, mutect2, varscan2
- HECW2 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 179/436 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); catalogued as COSV53648718, COSV53651582; called by muse, mutect2, varscan2
- HELB | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV56073581; called by muse, mutect2, varscan2
- HIVEP3 | c.7202G>A p.R2401K | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs760045015; called by muse, mutect2, varscan2
- HNRNPCL1 | c.145C>T p.H49Y | Missense Mutation (SNP) | VAF 84/403 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100509030; called by muse, mutect2, varscan2
- HOMEZ | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 160/426 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV100664152; called by muse, mutect2, varscan2
- HSP90AB1 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 119/329 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV100807074, COSV62335050; called by muse, mutect2, varscan2
- HYDIN | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865963159, COSV55475478; called by muse, mutect2, varscan2
- HYKK | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 157/253 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100856485; called by muse, mutect2, varscan2
- IGHE | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); catalogued as rs1555456547; called by muse, mutect2, varscan2
- IGSF10 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 131/362 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs1247321142, COSV99199924; called by muse, mutect2, varscan2
- IMPG2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 120/344 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs372789677; called by muse, mutect2, varscan2
- INSRR | c.2216G>A p.R739K | Missense Mutation (SNP) | VAF 306/479 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV63875317; called by muse, mutect2, varscan2
- IZUMO3 | c.626G>A p.R209Q (on ENST00000543880 / NM_001365008.2; = p.R203Q on NM_001271706.1) | Missense Mutation (SNP) | VAF 179/260 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.412); catalogued as rs10966335; called by muse, mutect2, varscan2
- JUP | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as rs782765314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNQ3 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 170/388 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV66473617; called by muse, mutect2, varscan2
- KCTD15 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 137/376 reads (36%) | catalogued as rs757471584, COSV52289992; called by muse, mutect2, varscan2
- KDM2B | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 121/374 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as rs782213024, COSV65639661; called by muse, mutect2, varscan2
- KIAA1217 | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 135/414 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776437777; called by muse, mutect2, varscan2
- KIF5C | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1299666658; called by muse, mutect2, varscan2
- KIR3DL2 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV54395691; called by muse, mutect2, varscan2
- KLB | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 167/465 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.165); catalogued as COSV57301665, COSV57304933; called by muse, mutect2, varscan2
- KLF18 | c.2989G>A p.D997N | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (1); catalogued as rs555970837; called by muse, mutect2, varscan2
- KLHDC7B | c.50G>A p.S17N (on ENST00000395676; = p.S658N on NM_138433.5) | Missense Mutation (SNP) | VAF 249/497 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as rs368890276; called by muse, mutect2, varscan2
- KMT2D | c.6889C>T p.P2297S | Missense Mutation (SNP) | VAF 191/518 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs748334191, COSV56452254; called by muse, varscan2
- KRT2 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 177/488 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs745616396; called by muse, mutect2, varscan2
- KRT5 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 137/489 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs978927000; called by muse, varscan2
- KRT6C | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 146/414 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs535131158, COSV52880586; called by muse, mutect2
- KRTAP24-1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 180/425 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs1226263131, COSV61088983, COSV61089648; called by muse, mutect2, varscan2
- KRTAP5-10 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 250/684 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.795); catalogued as rs1405100288; called by muse, mutect2
- L3MBTL4 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 143/366 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV53124618, COSV53137241; called by muse, mutect2, varscan2
- LHCGR | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 129/353 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54294600; called by muse, mutect2, varscan2
- LRIG1 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 125/359 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs1336674903; called by muse, mutect2, varscan2
- LRIG1 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 126/361 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs1418331241; called by muse, mutect2, varscan2
- LRRIQ1 | c.3700C>T p.H1234Y | Missense Mutation (SNP) | VAF 138/348 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1321601759, COSV67830042; called by muse, mutect2, varscan2
- LRRN1 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 134/351 reads (38%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.467); catalogued as rs771119775; called by muse, mutect2, varscan2
- LY6L | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 271/580 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs774634367; called by muse, mutect2, varscan2
- MAP3K9 | c.2383G>A p.E795K (on ENST00000554752 / NM_001284230.1; = p.E809K on NM_033141.4) | Missense Mutation (SNP) | VAF 163/430 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV67122281; called by muse, mutect2, varscan2
- MCTP2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 145/342 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1425029188, COSV59142077; called by muse, mutect2, varscan2
- MDN1 | c.11362G>A p.E3788K | Missense Mutation (SNP) | VAF 92/269 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs766485370; called by muse, mutect2, varscan2
- ME1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs780787550, COSV63839355; called by muse, mutect2, varscan2
- MEGF8 | c.6445C>T p.R2149C (on ENST00000251268 / NM_001271938.2; = p.R2082C on NM_001410.3) | Missense Mutation (SNP) | VAF 205/512 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.226); catalogued as rs367975745; called by muse, mutect2, varscan2
- MFSD10 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs916660747; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 284/356 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MLLT1 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 179/440 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1279997160; called by muse, mutect2, varscan2
- MMP1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 167/794 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs775721047; called by muse, mutect2, varscan2
- MMP10 | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 141/644 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs372673583; called by muse, mutect2, varscan2
- MORC2 | c.1904C>T p.P635L (on ENST00000397641 / NM_001303256.3; = p.P573L on NM_014941.3) | Missense Mutation (SNP) | VAF 170/597 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99309991, COSV99310602; called by muse, mutect2, varscan2
- MPP7 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 125/348 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1461447084; called by muse, mutect2, varscan2
- MROH1 | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 138/372 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs868520680; called by muse, mutect2, varscan2
- MTX3 | c.844C>T p.R282C (on ENST00000512528 / NM_001363818.2; = p.R221C on NM_001167741.2) | Missense Mutation (SNP) | VAF 126/327 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs767884268, COSV101560539, COSV72590927; called by muse, mutect2, varscan2
- MUC2 | c.4019C>T p.S1340L | Missense Mutation (SNP) | VAF 116/203 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs897610138; called by muse, mutect2, varscan2
- MUC22 | c.3694G>A p.G1232S | Missense Mutation (SNP) | VAF 266/724 reads (37%) | SIFT tolerated (0.62); catalogued as rs1044832810; called by muse, mutect2, varscan2
- MUC5B | c.9554C>T p.S3185F | Missense Mutation (SNP) | VAF 211/376 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs749527413; called by muse, mutect2, varscan2
- MUSK | c.1678C>T p.L560F | Missense Mutation (SNP) | VAF 212/332 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51879645; called by muse, mutect2, varscan2
- MXRA5 | c.6154G>A p.E2052K | Missense Mutation (SNP) | VAF 207/587 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs1463329092; called by muse, varscan2
- MYOC | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 167/523 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50674992; called by muse, mutect2, varscan2
- NAP1L3 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 155/467 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV59077003; called by muse, mutect2, varscan2
- NETO1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100199876, COSV55005785; called by muse, mutect2, varscan2
- NEXMIF | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 194/495 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50027658; called by muse, mutect2, varscan2
- NF1 | c.6820G>A p.A2274T (on ENST00000358273 / NM_001042492.3; = p.A2253T on NM_000267.3) | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as CD031067, COSV62205957; called by muse, mutect2, varscan2
- NFRKB | c.3868C>T p.P1290S (on ENST00000446488 / NM_001143835.2; = p.P1315S on NM_006165.3) | Missense Mutation (SNP) | VAF 113/185 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV99859265; called by muse, mutect2, varscan2
- NFRKB | c.1108C>T p.L370F (on ENST00000446488 / NM_001143835.2; = p.L395F on NM_006165.3) | Missense Mutation (SNP) | VAF 118/203 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs148289841; called by muse, mutect2, varscan2
- NGRN | c.631A>T p.N211Y | Missense Mutation (SNP) | VAF 140/892 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58960875, COSV58960976; called by muse, mutect2, varscan2
- NLRP11 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 113/283 reads (40%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.901); catalogued as rs749033575; called by muse, mutect2, varscan2
- NOBOX | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 264/334 reads (79%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.041); catalogued as COSV56192875; called by muse, mutect2, varscan2
- NOVA1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 119/362 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57490645; called by muse, varscan2
- NSG2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 109/353 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV100292681, COSV57459529; called by muse, mutect2, varscan2
- NYAP1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 672/846 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs1323532806; called by muse, mutect2, varscan2
- NYAP1 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 532/675 reads (79%) | SIFT tolerated (0.65); PolyPhen benign (0.047); catalogued as rs762146711, COSV55719186; called by muse, mutect2, varscan2
- OBSCN | c.11101G>A p.E3701K | Missense Mutation (SNP) | VAF 241/359 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV99472520; called by muse, mutect2, varscan2
- OR10A3 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 163/473 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.745); catalogued as COSV100660222; called by muse, mutect2, varscan2
- OR10R2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 143/474 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1352239072, COSV63768728; called by muse, mutect2, varscan2
- OR2T2 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 109/1694 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1274629943, COSV61618954, COSV61619014; called by muse, mutect2
- OR3A2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV99064963; called by muse, mutect2, varscan2
- OR4C16 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 149/401 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1565052193, COSV58942866; called by muse, mutect2, varscan2
- OR4D5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 159/258 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV58307045; called by muse, mutect2, varscan2
- OR6C4 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 91/275 reads (33%) | catalogued as COSV67793259; called by muse, mutect2, varscan2
- OR6F1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 78/680 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV57469321; called by muse, mutect2, varscan2
- OR7G1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 126/368 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.06); catalogued as COSV53318442; called by muse, mutect2
- PCDH19 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 221/558 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM149759, COSV55268388, COSV55268400; called by muse, mutect2, varscan2
- PCDHA8 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 168/491 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs1554139783, COSV65323830; called by muse, mutect2, varscan2
- PCDHB1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 174/460 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs782642827, COSV60630574; called by muse, mutect2, varscan2
- PCDHB3 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 105/313 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782801316, COSV50589763; called by muse, mutect2, varscan2
- PCDHB6 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 231/667 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs868915597, COSV50705762; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 73/506 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, mutect2, varscan2
- PCDHGB7 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 156/394 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs760626443; called by muse, mutect2, varscan2
- PCLO | c.9773A>T p.E3258V | Missense Mutation (SNP) | VAF 255/327 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483536249, COSV61654242; called by muse, mutect2, varscan2
- PCYT1A | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99491917; called by muse, mutect2, varscan2
- PDK3 | c.5G>C p.R2P | Missense Mutation (SNP) | VAF 112/281 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs758776608; called by muse, mutect2, varscan2
- PHF10 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 122/198 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59324824; called by muse, mutect2, varscan2
- PKHD1L1 | c.3200C>T p.P1067L | Missense Mutation (SNP) | VAF 123/404 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs368362467; called by muse, mutect2, varscan2
- PLCXD3 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 127/388 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as rs1293604632; called by muse, mutect2, varscan2
- POMP | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 128/319 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV66481678; called by muse, mutect2, varscan2
- PPP1R12B | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100408427; called by muse, varscan2
- PSG8 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 152/493 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV100125985; called by muse, mutect2, varscan2
- PTCHD3 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 171/471 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.022); catalogued as COSV71256324, COSV71256659; called by muse, mutect2, varscan2
- PTPRQ | c.6122C>T p.S2041L (on ENST00000616559; = p.S2008L on NM_001145026.2) | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs533166022, COSV57038362; called by muse, mutect2, varscan2
- PTPRT | c.2490C>T p.F830= | Splice Region (SNP) | VAF 99/270 reads (37%) | catalogued as COSV61962200; called by muse, mutect2, varscan2
- PUS10 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 107/313 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs756902274; called by muse, mutect2, varscan2
- RAB43 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754583631; called by muse, mutect2, varscan2
- RAPSN | c.1151A>G p.H384R | Missense Mutation (SNP) | VAF 140/416 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs775206324; called by muse, mutect2, varscan2
- RASA4 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs755207081; called by mutect2, varscan2
- RELCH | c.2566C>T p.H856Y | Missense Mutation (SNP) | VAF 118/345 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.891); catalogued as COSV99901617; called by muse, mutect2, varscan2
- RGS6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1469222528, COSV59573883; called by muse, mutect2, varscan2
- RGSL1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 183/292 reads (63%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.643); catalogued as rs1376505878; called by muse, mutect2, varscan2
- RIMBP3 | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 185/955 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238134728; called by muse, mutect2, varscan2
- ROBO2 | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 108/251 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs777014129, COSV59942276; called by muse, mutect2, varscan2
- RREB1 | c.3227C>T p.S1076F | Missense Mutation (SNP) | VAF 145/440 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs944325511; called by muse, mutect2, varscan2
- RUNX1T1 | c.91C>T p.R31C (on ENST00000265814 / NM_001198628.1; = p.R4C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/320 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs756333150, COSV56153978, COSV56159553; called by muse, mutect2, varscan2
- RYR1 | c.10730G>A p.R3577Q | Missense Mutation (SNP) | VAF 146/433 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs372914229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCIMP | c.210G>A p.E70= | Splice Region (SNP) | VAF 45/324 reads (14%) | catalogued as rs759770890; called by muse, mutect2, varscan2
- SCN3B | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 140/250 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); catalogued as COSV54800599; called by muse, mutect2, varscan2
- SDK1 | c.6044C>T p.A2015V | Missense Mutation (SNP) | VAF 139/591 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs767550382, COSV104432211; called by muse, mutect2, varscan2
- SEMA3F | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 125/335 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1038030098, COSV50029848; called by muse, mutect2, varscan2
- SEMA6D | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 143/246 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs755772605, COSV60380249; called by muse, mutect2, varscan2
- SIPA1L2 | c.4415C>T p.S1472L | Missense Mutation (SNP) | VAF 156/264 reads (59%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.842); catalogued as rs150962063, COSV53384982; called by muse, mutect2, varscan2
- SIPA1L3 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 168/502 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs1158336064; called by muse, mutect2, varscan2
- SLAIN1 | c.1541G>A p.G514E (on ENST00000466548; = p.G251E on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/426 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.639); catalogued as COSV57386805, COSV57388238; called by muse, mutect2, varscan2
- SLC15A5 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 98/185 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs963427797, COSV61362038; called by muse, mutect2, varscan2
- SLC25A45 | c.153C>T p.S51= | Splice Region (SNP) | VAF 115/349 reads (33%) | catalogued as rs570700909; called by muse, mutect2, varscan2
- SLC2A9 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 133/393 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121908322, CM086959, COSV53328945; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC35B1 | c.410C>T p.S137F (on ENST00000649906; = p.S100F on NM_005827.4) | Missense Mutation (SNP) | VAF 86/277 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as rs377737560; called by muse, mutect2, varscan2
- SLC9C1 | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 116/323 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59890173; called by muse, mutect2, varscan2
- SNAPC4 | c.2774C>T p.S925L | Missense Mutation (SNP) | VAF 262/389 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs377460643; called by muse, mutect2, varscan2
- SOCS7 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 119/215 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as rs773479428; called by muse, mutect2, varscan2
- SPEM3 | c.1569G>A p.W523* | Nonsense Mutation (SNP) | VAF 176/264 reads (67%) | catalogued as rs1171056691; called by muse, mutect2, varscan2
- SPHKAP | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 154/427 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV60867421; called by muse, mutect2, varscan2
- SPHKAP | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 176/472 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs148914025, COSV60868610; called by muse, mutect2, varscan2
- STAB1 | c.5489G>A p.R1830Q | Missense Mutation (SNP) | VAF 163/451 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as rs764397344, COSV58739787; called by muse, mutect2, varscan2
- SYNPO2 | c.2428C>T p.Q810* | Nonsense Mutation (SNP) | VAF 174/485 reads (36%) | catalogued as COSV61106864; called by muse, mutect2, varscan2
- TAF2 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65422654; called by muse, mutect2, varscan2
- TCF4 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 123/367 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV61897169; called by muse, mutect2, varscan2
- TENM4 | c.3664G>A p.G1222S | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs764166454, COSV53610557; called by muse, mutect2, varscan2
- THBS4 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs762665635; called by muse, mutect2, varscan2
- TIE1 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV65249342; called by muse, mutect2, varscan2
- TM4SF4 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 137/351 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1293337765, COSV59514955; called by muse, mutect2, varscan2
- TMC2 | c.1898G>A p.S633N | Missense Mutation (SNP) | VAF 126/332 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs894942795; called by muse, mutect2
- TMEM132C | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 170/485 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.493); catalogued as rs530322074; called by muse, mutect2, varscan2
- TNR | c.2528A>G p.N843S | Missense Mutation (SNP) | VAF 143/427 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV54904618; called by muse, mutect2, varscan2
- TP63 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 111/213 reads (52%) | catalogued as COSV53198553; called by muse, mutect2, varscan2
- TPST2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 255/540 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV58679171; called by muse, mutect2, varscan2
- TRAV5 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 115/354 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs779741225; called by muse, mutect2, varscan2
- TRIM49B | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 115/293 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV60320646; called by muse, mutect2, varscan2
- TRIM66 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 113/350 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs770144853, COSV55123976; called by muse, mutect2, varscan2
- TRIO | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 112/273 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV60082542; called by muse, mutect2, varscan2
- TRIO | c.7475C>T p.S2492F | Missense Mutation (SNP) | VAF 213/630 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs774046957; called by muse, mutect2, varscan2
- TRPV3 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 64/427 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs768484820; called by muse, mutect2, varscan2
- TTN | c.99535G>A p.E33179K (on ENST00000591111; = p.E25755K on NM_003319.4) | Missense Mutation (SNP) | VAF 135/340 reads (40%) | PolyPhen benign (0.268); catalogued as rs766062367, COSV59951999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.32095G>A p.E10699K (on ENST00000591111; = p.E9772K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/242 reads (37%) | PolyPhen benign (0); catalogued as rs188482293; called by muse, mutect2, varscan2
- TTN | c.2935G>A p.E979K (on ENST00000591111; = p.E933K on NM_003319.4) | Missense Mutation (SNP) | VAF 135/400 reads (34%) | PolyPhen probably damaging (0.994); catalogued as rs778333259, COSV60277428; called by muse, mutect2, varscan2
- TXNDC2 | c.325G>A p.E109K (on ENST00000306084 / NM_001098529.2; = p.E42K on NM_032243.6) | Missense Mutation (SNP) | VAF 189/501 reads (38%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.828); catalogued as COSV60154070; called by muse, mutect2, varscan2
- UBR4 | c.13871C>T p.S4624F | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV64394047; called by muse, mutect2, varscan2
- UGT2B4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV59315722; called by muse, mutect2, varscan2
- UNC5D | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 271/558 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54795571; called by muse, mutect2, varscan2
- USH2A | c.15089C>T p.S5030L | Missense Mutation (SNP) | VAF 129/428 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs758660532, CM073410, COSV100227233; called by muse, mutect2, varscan2
- USP26 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.058); catalogued as COSV63709702; called by muse, mutect2, varscan2
- VWA8 | c.5699C>T p.T1900I | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101023006; called by muse, mutect2, varscan2
- VWF | c.2965C>T p.Q989* | Nonsense Mutation (SNP) | VAF 84/142 reads (59%) | catalogued as COSV99778778; called by muse, mutect2, varscan2
- WSCD1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 98/628 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV58498447; called by muse, mutect2, varscan2
- ZBTB39 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 136/416 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178628656, COSV100267902; called by muse, mutect2, varscan2
- ZDHHC12 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 219/305 reads (72%) | catalogued as rs573686929; called by muse, mutect2, varscan2
- ZFHX2 | c.7063G>A p.G2355R | Missense Mutation (SNP) | VAF 195/530 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1235710220, COSV101352166; called by muse, mutect2, varscan2
- ZNF229 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 134/409 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs1236440808; called by muse, mutect2, varscan2
- ZNF280B | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.06); catalogued as COSV64528287; called by muse, mutect2, varscan2
- ZNF485 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 139/409 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs760403777; called by muse, mutect2, varscan2
- ZNF607 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 145/399 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs771243900, COSV67696506; called by muse, mutect2, varscan2
- ZNF705G | c.176T>C p.L59P | Missense Mutation (SNP) | VAF 125/440 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1385706652; called by muse, mutect2, varscan2
- ZNF770 | c.733del p.R245Gfs*5 | Frame Shift Del (DEL) | VAF 122/251 reads (49%) | catalogued as COSV62544465; called by mutect2, pindel, varscan2
- ZNF81 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.441); catalogued as COSV100096265; called by muse, mutect2, varscan2
- ZNF831 | c.3461C>T p.S1154F | Missense Mutation (SNP) | VAF 160/511 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV64038424; called by muse, mutect2, varscan2
- ZNF888 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 105/147 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1050512032; called by muse, mutect2, varscan2
- ZSCAN10 | c.1033G>A p.D345N (on ENST00000252463; = p.D400N on NM_032805.3) | Missense Mutation (SNP) | VAF 157/500 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs866962910, COSV99374179; called by muse, mutect2, varscan2
- ABCA12 | c.5502G>A p.W1834* (on ENST00000272895 / NM_173076.3; = p.W1516* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 122/367 reads (33%) | called by muse, mutect2, varscan2
- ABCA13 | c.12235G>A p.V4079I | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ABCA5 | c.2782C>T p.L928F | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ABCA9 | c.4072G>A p.G1358R | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ABCC5 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 127/347 reads (37%) | called by muse, mutect2, varscan2
- ABI3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 134/354 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ADAM20 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY1 | c.2942T>C p.V981A | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ADGRE1 | c.2509G>A p.G837R | Missense Mutation (SNP) | VAF 119/289 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADH1B | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 175/470 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADRA2B | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 163/453 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- AGTPBP1 | c.2753G>C p.R918P (on ENST00000357081 / NM_001330701.2; = p.R878P on NM_015239.2) | Missense Mutation (SNP) | VAF 126/187 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALK | c.3960G>A p.W1320* | Nonsense Mutation (SNP) | VAF 72/215 reads (33%) | called by muse, mutect2, varscan2
- ALMS1 | c.10700T>G p.V3567G | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANAPC5 | c.1904G>A p.G635E | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ANO3 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AP3B2 | c.2971G>A p.E991K (on ENST00000261722; = p.E985K on NM_004644.5) | Missense Mutation (SNP) | VAF 102/161 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBB1IP | c.1370-1G>A p.X457_splice | Splice Site (SNP) | VAF 77/221 reads (35%) | called by muse, mutect2, varscan2
- APC2 | c.5873G>A p.G1958E | Missense Mutation (SNP) | VAF 186/504 reads (37%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ARAF | c.1682C>A p.P561H | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGAP3 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 121/424 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARMC10 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- ASPM | c.2520T>A p.D840E | Missense Mutation (SNP) | VAF 52/413 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ATOX1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ATP13A5 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 109/261 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATP1B1 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 245/388 reads (63%) | called by muse, mutect2, varscan2
- ATP2B3 | c.3079C>G p.P1027A | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BMP7 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 158/471 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BMP7 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 159/471 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRCA1 | c.4157C>T p.S1386F | Missense Mutation (SNP) | VAF 115/204 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- BSN | c.8293C>T p.P2765S | Missense Mutation (SNP) | VAF 147/424 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C3orf56 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 86/230 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- C4orf54 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 119/271 reads (44%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C5 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 147/215 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1D | c.5099C>T p.S1700F (on ENST00000350061 / NM_001128840.3; = p.S1720F on NM_000720.4) | Missense Mutation (SNP) | VAF 125/384 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1E | c.6487C>T p.P2163S (on ENST00000367573 / NM_001205293.3; = p.P2120S on NM_000721.4) | Missense Mutation (SNP) | VAF 74/582 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1F | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 163/456 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- CACNA2D1 | c.193_198del p.Q65_D66del | In Frame Del (DEL) | VAF 93/253 reads (37%) | called by mutect2, pindel, varscan2
- CAND1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CATSPERB | c.657T>A p.D219E | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD2 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 77/364 reads (21%) | called by muse, mutect2, varscan2
- CEP290 | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP47 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 130/388 reads (34%) | called by muse, varscan2
- CFAP61 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHGA | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 139/377 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CHIT1 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.017); called by muse, varscan2
- CHRNA6 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 157/495 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CLSPN | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 54/251 reads (22%) | called by muse, mutect2, varscan2
- COL14A1 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- COPS8 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- COQ8A | c.695T>G p.V232G | Missense Mutation (SNP) | VAF 76/522 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPNE3 | c.905A>T p.N302I | Missense Mutation (SNP) | VAF 190/381 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CROCC2 | c.4469C>T p.A1490V | Missense Mutation (SNP) | VAF 138/402 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CTSC | c.314T>A p.F105Y | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CWC22 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 157/390 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- CYP4B1 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 68/284 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CYP4B1 | c.1071G>A p.W357* | Nonsense Mutation (SNP) | VAF 37/154 reads (24%) | called by muse, mutect2, varscan2
- DAO | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 148/392 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DARS1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 118/341 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DEPP1 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 141/401 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- DERPC | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 130/273 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- DES | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 135/324 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEUP1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 112/326 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DIXDC1 | c.1903G>C p.D635H (on ENST00000440460 / NM_001037954.4; = p.D424H on NM_033425.4) | Missense Mutation (SNP) | VAF 101/182 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- DLX3 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- DNAH11 | c.4388A>G p.E1463G | Missense Mutation (SNP) | VAF 206/354 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DNAH12 | c.7912A>C p.K2638Q (on ENST00000351747; = p.K3506Q on NM_001366028.2) | Missense Mutation (SNP) | VAF 101/226 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- DNAH3 | c.8129C>T p.T2710I | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK1 | c.4998-1G>A p.X1666_splice | Splice Site (SNP) | VAF 78/267 reads (29%) | called by muse, mutect2, varscan2
- EEF1A1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EEF2K | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 110/344 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEPD1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 374/633 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- EIF1AD | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 97/270 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- EIF3M | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 71/275 reads (26%) | called by muse, mutect2, varscan2
- ERICH3 | c.4540_4557del p.V1514_E1519del | In Frame Del (DEL) | VAF 35/245 reads (14%) | called by mutect2, pindel, varscan2
- EZH2 | c.1310C>T p.A437V (on ENST00000460911 / NM_001203247.2; = p.A442V on NM_004456.5) | Missense Mutation (SNP) | VAF 360/458 reads (79%) | SIFT tolerated (0.19); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FAM13B | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 149/457 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- FBRS | c.1349C>T p.P450L (on ENST00000287468; = p.P970L on NM_001105079.3) | Missense Mutation (SNP) | VAF 245/548 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.687); called by muse, varscan2
- FEM1C | c.202A>T p.I68L | Missense Mutation (SNP) | VAF 161/433 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FYB2 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FYN | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 150/253 reads (59%) | called by muse, mutect2, varscan2
- GABRE | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GEMIN5 | c.3878C>T p.S1293F | Missense Mutation (SNP) | VAF 186/443 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GIMD1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 136/384 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- GJA10 | c.1475A>T p.K492I | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- GOLGA8M | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 147/286 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- GOLGA8S | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- GPLD1 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 120/311 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- GPT2 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 90/289 reads (31%) | called by muse, mutect2, varscan2
- GRIA2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 100/323 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- GRXCR2 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 205/534 reads (38%) | called by muse, mutect2, varscan2
- GUCY2C | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 167/278 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GUCY2F | c.1798G>T p.D600Y | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HDHD2 | c.397T>C p.L133= | Splice Region (SNP) | VAF 78/174 reads (45%) | called by muse, mutect2, varscan2
- HECW1 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 470/810 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HMGB3 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 110/358 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by mutect2, varscan2
- HNRNPA1P48 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 234/517 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HOXD9 | c.356G>A p.W119* | Nonsense Mutation (SNP) | VAF 184/470 reads (39%) | called by muse, mutect2, varscan2
- IDH3B | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGKV2-24 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 87/230 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- IL17REL | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 133/458 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL31 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- INSRR | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 67/492 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- INSYN2B | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 150/416 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS8 | c.1552T>A p.L518M | Missense Mutation (SNP) | VAF 177/336 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ITGA5 | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 111/278 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JMJD1C | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- KANK1 | c.2075T>C p.I692T | Missense Mutation (SNP) | VAF 216/326 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNG1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 195/531 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KCNU1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 107/326 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIAA0825 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF13B | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 97/355 reads (27%) | called by muse, mutect2, varscan2
- KIF17 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 152/361 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIF21B | c.3370A>G p.M1124V | Missense Mutation (SNP) | VAF 61/383 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLRD1 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 92/151 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP10-5 | c.227C>G p.P76R | Missense Mutation (SNP) | VAF 264/739 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- KSR1 | c.2348A>C p.Y783S (on ENST00000644974 / NM_001367810.1; = p.Y668S on NM_014238.2) | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- LEF1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 134/396 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- LIPK | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 99/273 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- LRBA | c.6701G>A p.G2234E | Missense Mutation (SNP) | VAF 80/188 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYG1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 118/299 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYST | c.10427C>T p.P3476L | Missense Mutation (SNP) | VAF 126/588 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- LYST | c.3946G>T p.V1316L | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- MACF1 | c.8798C>T p.S2933L | Missense Mutation (SNP) | VAF 50/191 reads (26%) | called by muse, mutect2, varscan2
- MAGEB5 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MAGEC2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 206/588 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MAN2B1 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MAP1B | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 138/381 reads (36%) | called by muse, mutect2, varscan2
- MAP3K3 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 141/359 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MARCO | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 177/515 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAST1 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 180/464 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBOAT1 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ME3 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MICB | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 179/508 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MROH5 | c.2294T>C p.V765A | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MRTFB | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 110/398 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MTOR | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MUC16 | c.16370C>T p.S5457F | Missense Mutation (SNP) | VAF 188/457 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MXRA5 | c.6769T>A p.Y2257N | Missense Mutation (SNP) | VAF 239/597 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.6230C>T p.P2077L | Missense Mutation (SNP) | VAF 184/550 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- MYL7 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 109/523 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO9A | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 122/190 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEA | c.7963C>T p.P2655S | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEB | c.4297G>A p.D1433N | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- NEK1 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NF1 | c.984T>A p.C328* | Nonsense Mutation (SNP) | VAF 131/228 reads (57%) | called by muse, mutect2, varscan2
- NID2 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 182/514 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NLRP5 | c.2807C>T p.T936I | Missense Mutation (SNP) | VAF 121/298 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- NRK | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 148/406 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBSCN | c.11965G>A p.E3989K | Missense Mutation (SNP) | VAF 151/500 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- OR10H1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 202/467 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- OR2AP1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51A7 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 114/345 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR51I1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR9G1 | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 177/884 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OTUD5 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); called by muse, varscan2
- PAPLN | c.2213T>C p.L738P (on ENST00000554301; = p.L711P on NM_173462.4) | Missense Mutation (SNP) | VAF 140/367 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PARD3B | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 124/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDZD2 | c.2005G>A p.V669I | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- PIWIL1 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 185/487 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PKHD1L1 | c.5318G>A p.G1773E | Missense Mutation (SNP) | VAF 141/489 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PLIN4 | c.3431G>A p.G1144E (on ENST00000301286; = p.G1159E on NM_001367868.2) | Missense Mutation (SNP) | VAF 148/418 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, varscan2
- PLOD2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNRC2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- POLQ | c.5134G>A p.A1712T | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PPP2R1A | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- PPP2R2C | c.1262A>G p.H421R | Missense Mutation (SNP) | VAF 195/465 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PQBP1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 122/396 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, varscan2
- PRRC2A | c.3058C>T p.P1020S | Missense Mutation (SNP) | VAF 276/696 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PTER | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 141/395 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTGS2 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 83/325 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- PTPRG | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PTPRQ | c.3643C>T p.P1215S (on ENST00000616559; = p.P1173S on NM_001145026.2) | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PWWP3B | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 190/444 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PWWP3B | c.1876A>G p.T626A | Missense Mutation (SNP) | VAF 148/383 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- QRICH2 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 214/565 reads (38%) | called by muse, mutect2, varscan2
- RAB5A | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- RAI1 | c.4709C>T p.P1570L | Missense Mutation (SNP) | VAF 266/586 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, varscan2
- RALGPS2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- RAPGEF4 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- RASA4B | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 80/498 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- RBBP6 | c.4216C>T p.R1406* | Nonsense Mutation (SNP) | VAF 189/416 reads (45%) | called by muse, mutect2, varscan2
- RLF | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RP1 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 155/396 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- RP1 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 184/401 reads (46%) | called by muse, mutect2, varscan2
- RSPO1 | c.93_94+1del p.X31_splice | Splice Site (DEL) | VAF 93/240 reads (39%) | called by mutect2, pindel, varscan2
- RXRB | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 95/272 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SEMA3E | c.1397T>A p.I466N | Missense Mutation (SNP) | VAF 125/182 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEMA3G | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SERPINA3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 155/403 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SETD1B | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 220/523 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGSM1 | c.694A>C p.S232R | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SHROOM1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 135/358 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SLC1A2 | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC2A6 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 241/360 reads (67%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.935); called by muse, varscan2
- SLC34A1 | c.1345A>T p.I449F | Missense Mutation (SNP) | VAF 86/291 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC6A14 | c.98A>C p.N33T | Missense Mutation (SNP) | VAF 141/414 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- SLC9C2 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1987T>A p.W663R (on ENST00000540229 / NM_001371097.1; = p.W602R on NM_001009562.4) | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT2 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- SMIM2 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 118/338 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SNAP91 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SNCAIP | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 160/428 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA45 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 277/484 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPINT2 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 83/247 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- STAB1 | c.2195G>T p.C732F | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STARD8 | c.2589G>A p.W863* | Nonsense Mutation (SNP) | VAF 150/441 reads (34%) | called by muse, mutect2, varscan2
- STEAP1B | c.307T>A p.S103T | Missense Mutation (SNP) | VAF 118/533 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- STEAP4 | c.724A>T p.I242F | Missense Mutation (SNP) | VAF 324/421 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- STK24 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 130/413 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TENT5D | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 178/418 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- THRB | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 170/421 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TICRR | c.4519C>T p.P1507S | Missense Mutation (SNP) | VAF 150/843 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, varscan2
- TIGD1 | c.824G>A p.W275* | Nonsense Mutation (SNP) | VAF 88/238 reads (37%) | called by muse, mutect2
- TMPRSS11A | c.832G>T p.V278F | Missense Mutation (SNP) | VAF 189/509 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- TNKS1BP1 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 123/409 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNKS2 | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TNRC6A | c.2718T>G p.N906K | Missense Mutation (SNP) | VAF 212/475 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TNXB | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 133/372 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TOPAZ1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 120/376 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- TOPBP1 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TREML1 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TRIM71 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 190/481 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TRIP12 | c.3361C>T p.Q1121* | Nonsense Mutation (SNP) | VAF 123/363 reads (34%) | called by muse, mutect2, varscan2
- TRPC4 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- UBTFL1 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 149/408 reads (37%) | called by muse, mutect2, varscan2
- URB2 | c.2229T>G p.I743M | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- USP17L1 | c.1215A>C p.Q405H | Missense Mutation (SNP) | VAF 135/416 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- USP24 | c.1316A>C p.N439T | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- WDFY4 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 110/367 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR87 | c.6757G>A p.E2253K | Missense Mutation (SNP) | VAF 161/452 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- WWOX | c.1194G>A p.W398* | Nonsense Mutation (SNP) | VAF 155/482 reads (32%) | called by muse, mutect2, varscan2
- ZBED9 | c.3664A>C p.T1222P | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ZBTB40 | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 154/307 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZDHHC18 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMYM3 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 227/573 reads (40%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ZNF160 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 167/429 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF382 | c.772C>G p.H258D | Missense Mutation (SNP) | VAF 143/374 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ZNF541 | c.3224G>A p.G1075E | Missense Mutation (SNP) | VAF 154/440 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF585A | c.1366C>T p.H456Y (on ENST00000292841 / NM_001288800.2; = p.H401Y on NM_152655.3) | Missense Mutation (SNP) | VAF 134/363 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF609 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF729 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 95/330 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ABCB5 | c.3333C>T p.I1111= (on ENST00000404938 / NM_001163941.2; = p.I666= on NM_178559.6) | Silent (SNP) | VAF 166/709 reads (23%) | catalogued as rs779852805; called by muse, mutect2, varscan2
- ABCC6 | c.3783G>A p.Q1261= | Silent (SNP) | VAF 159/608 reads (26%) | catalogued as rs964712550; called by muse, mutect2
- ABO | c.397C>T p.L133= | Silent (SNP) | VAF 107/164 reads (65%) | catalogued as rs548821343; called by muse, mutect2, varscan2
- ABO | c.396C>T p.F132= | Silent (SNP) | VAF 107/162 reads (66%) | catalogued as rs531314245; called by muse, mutect2, varscan2
- ACO2 | c.459C>T p.F153= | Silent (SNP) | VAF 127/398 reads (32%) | called by muse, mutect2, varscan2
- ACSM6 | c.33C>T p.V11= | Silent (SNP) | VAF 193/372 reads (52%) | called by muse, mutect2, varscan2
- ACTG2 | c.1059C>T p.F353= | Silent (SNP) | VAF 157/401 reads (39%) | catalogued as rs1444126627, COSV61828440; called by muse, mutect2, varscan2
- ADAD1 | c.45C>T p.S15= | Silent (SNP) | VAF 115/311 reads (37%) | called by muse, mutect2, varscan2
- ADAM28 | c.1686G>A p.G562= | Silent (SNP) | VAF 132/306 reads (43%) | catalogued as COSV56107514; called by muse, mutect2, varscan2
- ADAMTS15 | c.639C>T p.F213= | Silent (SNP) | VAF 197/328 reads (60%) | catalogued as COSV54505760, COSV54507611; called by muse, mutect2, varscan2
- AFMID | c.390C>T p.P130= | Silent (SNP) | VAF 135/329 reads (41%) | catalogued as COSV59976067; called by muse, mutect2, varscan2
- AGXT | c.366A>G p.R122= | Silent (SNP) | VAF 112/323 reads (35%) | called by muse, mutect2, varscan2
- ANKLE1 | c.1413C>T p.G471= (on ENST00000394458; = p.G417= on NM_152363.6) | Silent (SNP) | VAF 124/364 reads (34%) | called by muse, mutect2, varscan2
- AP3D1 | c.1725C>T p.I575= | Silent (SNP) | VAF 127/328 reads (39%) | called by muse, mutect2, varscan2
- APOB | c.9G>A p.P3= | Silent (SNP) | VAF 133/352 reads (38%) | catalogued as rs1426179585; called by muse, varscan2
- ARHGAP6 | c.2172G>A p.G724= | Silent (SNP) | VAF 152/443 reads (34%) | catalogued as COSV100273584; called by muse, mutect2, varscan2
- ATP12A | c.1557C>T p.L519= | Silent (SNP) | VAF 136/396 reads (34%) | catalogued as COSV54515963; called by muse, mutect2, varscan2
- ATP6V0A2 | c.672C>T p.V224= | Silent (SNP) | VAF 118/318 reads (37%) | called by muse, mutect2, varscan2
- ATP9A | c.1344C>T p.V448= | Silent (SNP) | VAF 199/526 reads (38%) | called by muse, mutect2, varscan2
- BLNK | c.510C>T p.G170= | Silent (SNP) | VAF 100/403 reads (25%) | called by muse, mutect2, varscan2
- BRINP1 | c.1635C>T p.S545= | Silent (SNP) | VAF 180/269 reads (67%) | called by muse, mutect2, varscan2
- BTC | c.99G>A p.G33= | Silent (SNP) | VAF 73/242 reads (30%) | called by muse, mutect2, varscan2
- C1R | c.1575G>T p.A525= (on ENST00000536053 / NM_001354346.2; = p.A511= on NM_001733.7) | Silent (SNP) | VAF 183/303 reads (60%) | catalogued as COSV73383002; called by muse, mutect2, varscan2
- C2orf49 | c.468C>T p.S156= | Silent (SNP) | VAF 108/303 reads (36%) | catalogued as rs1473878863; called by muse, mutect2, varscan2
- C7 | c.549C>T p.V183= | Silent (SNP) | VAF 105/289 reads (36%) | catalogued as COSV57472901; called by muse, mutect2, varscan2
- CACNA2D3 | c.2562G>A p.V854= | Silent (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
- CBFA2T2 | c.1200G>T p.G400= | Silent (SNP) | VAF 135/384 reads (35%) | called by muse, mutect2, varscan2
- CCER1 | c.1041G>A p.L347= | Silent (SNP) | VAF 181/508 reads (36%) | called by muse, mutect2, varscan2
- CCNB3 | c.2070C>T p.F690= | Silent (SNP) | VAF 170/511 reads (33%) | called by muse, mutect2, varscan2
- CDH23 | c.1788C>T p.I596= | Silent (SNP) | VAF 131/353 reads (37%) | catalogued as COSV54950177; called by muse, mutect2, varscan2
- CELSR3 | c.6459C>T p.P2153= | Silent (SNP) | VAF 126/322 reads (39%) | catalogued as rs184721547; called by muse, mutect2, varscan2
- CFAP47 | c.2052G>A p.A684= | Silent (SNP) | VAF 126/384 reads (33%) | catalogued as rs373860011, COSV52880660; called by muse, varscan2
- CFAP47 | c.3507G>A p.S1169= | Silent (SNP) | VAF 79/225 reads (35%) | catalogued as rs1200648270; called by muse, mutect2, varscan2
- CHD6 | c.2160C>T p.S720= | Silent (SNP) | VAF 163/400 reads (41%) | catalogued as rs989603311; called by muse, mutect2, varscan2
- CHFR | c.426C>T p.F142= | Silent (SNP) | VAF 116/311 reads (37%) | catalogued as COSV99905426; called by muse, mutect2, varscan2
- CLTC | c.3156C>T p.A1052= | Silent (SNP) | VAF 146/392 reads (37%) | called by muse, mutect2, varscan2
- CNOT9 | c.393C>T p.P131= | Silent (SNP) | VAF 105/304 reads (35%) | called by muse, mutect2, varscan2
- CNTN5 | c.1212G>A p.G404= | Silent (SNP) | VAF 115/324 reads (35%) | called by muse, mutect2, varscan2
- COL23A1 | c.1002C>T p.I334= | Silent (SNP) | VAF 167/444 reads (38%) | catalogued as rs1392733454; called by muse, mutect2, varscan2
- COL5A2 | c.3348G>A p.G1116= | Silent (SNP) | VAF 87/288 reads (30%) | catalogued as rs1553513577, COSV66416547; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL6A3 | c.7983C>T p.F2661= | Silent (SNP) | VAF 155/457 reads (34%) | catalogued as rs375222168; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COQ8A | c.696C>T p.V232= | Silent (SNP) | VAF 73/515 reads (14%) | catalogued as rs1000444018; called by muse, mutect2, varscan2
- CORO6 | c.291C>T p.I97= | Silent (SNP) | VAF 89/551 reads (16%) | catalogued as rs372494637; called by muse, mutect2, varscan2
- CPAMD8 | c.5727C>T p.F1909= (on ENST00000651564; = p.F1862= on NM_015692.5) | Silent (SNP) | VAF 150/380 reads (39%) | catalogued as rs750639642, COSV50186403; called by muse, mutect2, varscan2
- CRMP1 | c.1077G>A p.E359= | Silent (SNP) | VAF 126/368 reads (34%) | catalogued as rs774352363, COSV61483797; called by muse, mutect2, varscan2
- CSMD1 | c.5448C>T p.S1816= (on ENST00000520002; = p.S1815= on NM_033225.6) | Silent (SNP) | VAF 76/266 reads (29%) | catalogued as rs868286788, COSV100147568; called by muse, varscan2
- CTNS | c.642C>G p.V214= | Silent (SNP) | VAF 28/413 reads (7%) | catalogued as rs760843675; called by muse, mutect2
- CUX2 | c.3294G>A p.K1098= | Silent (SNP) | VAF 159/437 reads (36%) | called by muse, mutect2, varscan2
- DCAF12 | c.1155C>T p.P385= | Silent (SNP) | VAF 177/279 reads (63%) | called by muse, mutect2, varscan2
- DLGAP1 | c.843C>T p.S281= | Silent (SNP) | VAF 195/477 reads (41%) | called by muse, mutect2, varscan2
- DNAH5 | c.6558G>A p.R2186= | Silent (SNP) | VAF 95/285 reads (33%) | catalogued as COSV54205827; called by muse, mutect2, varscan2
- DRD3 | c.145C>T p.L49= | Silent (SNP) | VAF 178/519 reads (34%) | called by muse, mutect2, varscan2
- DSCAM | c.663G>A p.A221= | Silent (SNP) | VAF 84/213 reads (39%) | catalogued as rs767731476, COSV68024612; called by muse, mutect2, varscan2
- EBF3 | c.1689C>T p.F563= (on ENST00000355311 / NM_001375392.1; = p.F518= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 404/699 reads (58%) | catalogued as rs373301366; called by muse, mutect2, varscan2
- EFCAB1 | c.130C>T p.L44= | Silent (SNP) | VAF 243/493 reads (49%) | called by muse, mutect2, varscan2
- EFCAB12 | c.1044C>T p.I348= | Silent (SNP) | VAF 92/259 reads (36%) | catalogued as COSV58177494; called by muse, mutect2, varscan2
- EFHD2 | c.531C>T p.L177= | Silent (SNP) | VAF 248/486 reads (51%) | catalogued as rs1216204833; called by muse, mutect2, varscan2
- EGFLAM | c.127C>T p.L43= | Silent (SNP) | VAF 124/322 reads (39%) | called by muse, mutect2, varscan2
- ELFN1 | c.2223C>T p.T741= | Silent (SNP) | VAF 227/1362 reads (17%) | catalogued as rs1242537401; called by muse, mutect2, varscan2
- ELP3 | c.1383C>T p.F461= | Silent (SNP) | VAF 241/486 reads (50%) | called by muse, mutect2, varscan2
- ELP5 | c.420G>A p.Q140= | Silent (SNP) | VAF 253/350 reads (72%) | called by muse, mutect2, varscan2
- EPHA4 | c.2664G>A p.L888= | Silent (SNP) | VAF 118/349 reads (34%) | called by muse, mutect2, varscan2
- EPN1 | c.639C>T p.L213= | Silent (SNP) | VAF 157/395 reads (40%) | called by muse, mutect2, varscan2
- ESS2 | c.1344A>G p.T448= | Silent (SNP) | VAF 212/561 reads (38%) | called by muse, mutect2, varscan2
- FAM160A1 | c.2676C>T p.S892= | Silent (SNP) | VAF 145/378 reads (38%) | called by muse, mutect2, varscan2
- FAT4 | c.7383C>T p.V2461= | Silent (SNP) | VAF 118/356 reads (33%) | called by muse, mutect2, varscan2
- FAT4 | c.7650G>A p.K2550= | Silent (SNP) | VAF 140/364 reads (38%) | called by muse, mutect2, varscan2
- FAT4 | c.9894C>T p.P3298= | Silent (SNP) | VAF 116/363 reads (32%) | catalogued as rs1321137713; called by muse, mutect2, varscan2
- FCER2 | c.30G>A p.E10= | Silent (SNP) | VAF 113/276 reads (41%) | catalogued as rs1424828046; called by muse, mutect2, varscan2
- FGFRL1 | c.210C>T p.I70= | Silent (SNP) | VAF 232/605 reads (38%) | called by muse, mutect2, varscan2
- FN1 | c.1965G>A p.K655= | Silent (SNP) | VAF 84/225 reads (37%) | catalogued as COSV60554499; called by muse, mutect2, varscan2
- FOXA2 | c.237G>A p.G79= (on ENST00000377115 / NM_153675.3; = p.G85= on NM_021784.5) | Silent (SNP) | VAF 196/535 reads (37%) | catalogued as COSV65797157; called by muse, mutect2, varscan2
- FOXD4L5 | c.507C>T p.I169= | Silent (SNP) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- FRMPD4 | c.1395C>T p.S465= | Silent (SNP) | VAF 175/516 reads (34%) | catalogued as COSV66213588; called by muse, mutect2, varscan2
- GCSAML | c.285C>T p.L95= | Silent (SNP) | VAF 138/627 reads (22%) | catalogued as COSV100825900, COSV63577280; called by muse, mutect2, varscan2
- GIMAP6 | c.348C>T p.I116= | Silent (SNP) | VAF 431/555 reads (78%) | catalogued as rs776667788, COSV61033385; called by muse, mutect2, varscan2
- GJA3 | c.117C>T p.A39= | Silent (SNP) | VAF 170/452 reads (38%) | catalogued as COSV99576274; called by muse, varscan2
- GLI2 | c.4359G>A p.R1453= (on ENST00000361492 / NM_001374353.1; = p.R1470= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 196/496 reads (40%) | catalogued as COSV58037191; called by muse, mutect2, varscan2
- GPBP1 | c.270C>T p.Y90= | Silent (SNP) | VAF 142/408 reads (35%) | catalogued as COSV53311688; called by muse, mutect2, varscan2
- GPHN | c.138T>A p.P46= | Silent (SNP) | VAF 96/231 reads (42%) | called by muse, mutect2, varscan2
- GPR75 | c.693G>A p.K231= | Silent (SNP) | VAF 176/408 reads (43%) | catalogued as COSV100765711; called by muse, mutect2, varscan2
- GPRASP1 | c.1590G>A p.V530= | Silent (SNP) | VAF 212/559 reads (38%) | called by muse, mutect2, varscan2
- GRAP2 | c.240C>T p.F80= | Silent (SNP) | VAF 162/583 reads (28%) | catalogued as rs1189200477; called by muse, mutect2, varscan2
- GRM6 | c.1089G>A p.E363= | Silent (SNP) | VAF 122/323 reads (38%) | catalogued as COSV51436137; called by muse, mutect2, varscan2
- GRSF1 | c.555C>A p.L185= | Silent (SNP) | VAF 136/363 reads (37%) | called by muse, mutect2, varscan2
- HEATR5B | c.5073G>A p.E1691= | Silent (SNP) | VAF 84/253 reads (33%) | catalogued as rs1282760791; called by muse, mutect2, varscan2
- HELB | c.1452C>T p.I484= | Silent (SNP) | VAF 140/393 reads (36%) | catalogued as rs375638144; called by muse, mutect2, varscan2
- HIVEP3 | c.2574C>T p.I858= | Silent (SNP) | VAF 130/299 reads (43%) | called by muse, mutect2, varscan2
- HOMEZ | c.1377C>T p.P459= | Silent (SNP) | VAF 161/427 reads (38%) | called by muse, mutect2, varscan2
- HTR1A | c.699G>A p.V233= | Silent (SNP) | VAF 173/477 reads (36%) | called by muse, mutect2, varscan2
- IGFBP6 | c.711G>A p.G237= | Silent (SNP) | VAF 109/324 reads (34%) | catalogued as rs1203765091; called by muse, mutect2, varscan2
- IGHV1-18 | c.27C>T p.F9= | Silent (SNP) | VAF 83/323 reads (26%) | called by muse, mutect2, varscan2
- IGHV3-20 | c.234T>C p.G78= | Silent (SNP) | VAF 134/508 reads (26%) | catalogued as rs1390193106; called by muse, mutect2, varscan2
- IGHV3-21 | c.249G>A p.V83= | Silent (SNP) | VAF 132/576 reads (23%) | called by muse, varscan2
- IGKV1-17 | c.51C>T p.F17= | Silent (SNP) | VAF 176/498 reads (35%) | called by muse, mutect2, varscan2
- IGLV3-10 | c.18C>T p.L6= | Silent (SNP) | VAF 159/339 reads (47%) | catalogued as rs1157984963; called by muse, mutect2, varscan2
- IVL | c.1164G>A p.E388= | Silent (SNP) | VAF 165/753 reads (22%) | catalogued as COSV64216902; called by mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 77/242 reads (32%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2, varscan2
- KCNH6 | c.1164G>A p.R388= | Silent (SNP) | VAF 174/463 reads (38%) | called by muse, mutect2, varscan2
- KCNJ12 | c.36C>T p.I12= | Silent (SNP) | VAF 210/1111 reads (19%) | catalogued as rs567413846, COSV59164690, COSV59176050; called by muse, mutect2
- KCNK2 | c.108G>C p.S36= (on ENST00000444842 / NM_001017425.3; = p.S21= on NM_014217.4) | Silent (SNP) | VAF 137/403 reads (34%) | catalogued as rs1481663513, COSV67204836; called by muse, mutect2, varscan2
- KCNK5 | c.1392C>T p.F464= | Silent (SNP) | VAF 179/470 reads (38%) | catalogued as COSV63989069; called by muse, mutect2, varscan2
- KCTD6 | c.195C>T p.F65= | Silent (SNP) | VAF 164/457 reads (36%) | catalogued as rs766262860; called by muse, mutect2, varscan2
- KDM6A | c.3054G>A p.K1018= | Silent (SNP) | VAF 75/406 reads (18%) | called by muse, mutect2, varscan2
- KIF22 | c.1122C>T p.T374= | Silent (SNP) | VAF 177/345 reads (51%) | called by muse, mutect2, varscan2
- KRT5 | c.711G>A p.R237= | Silent (SNP) | VAF 135/483 reads (28%) | called by muse, varscan2
- KRT6C | c.1008G>A p.E336= | Silent (SNP) | VAF 145/408 reads (36%) | called by muse, mutect2
- KRT80 | c.753C>T p.I251= | Silent (SNP) | VAF 188/536 reads (35%) | catalogued as rs746844184; called by muse, mutect2, varscan2
- L3MBTL1 | c.1200G>A p.K400= (on ENST00000418998 / NM_001377303.1; = p.K310= on NM_015478.7) | Silent (SNP) | VAF 111/334 reads (33%) | catalogued as rs1298648272; called by muse, mutect2, varscan2
- L3MBTL1 | c.2094C>T p.S698= (on ENST00000418998 / NM_001377303.1; = p.S608= on NM_015478.7) | Silent (SNP) | VAF 133/382 reads (35%) | called by muse, mutect2, varscan2
- LILRA1 | c.405G>A p.V135= | Silent (SNP) | VAF 170/484 reads (35%) | catalogued as rs1260779642; called by muse, mutect2, varscan2
- LILRB1 | c.162G>A p.R54= (on ENST00000427581; = p.R18= on NM_006669.6) | Silent (SNP) | VAF 179/552 reads (32%) | catalogued as rs569262462; called by muse, mutect2, varscan2
- LRFN2 | c.1701G>A p.K567= | Silent (SNP) | VAF 148/430 reads (34%) | catalogued as COSV57834898; called by muse, mutect2, varscan2
- LRRC37B | c.147T>C p.S49= | Silent (SNP) | VAF 167/260 reads (64%) | called by muse, mutect2, varscan2
- LRRTM4 | c.27G>A p.L9= | Silent (SNP) | VAF 100/302 reads (33%) | catalogued as COSV69141105; called by muse, mutect2, varscan2
- MAGEA3 | c.390C>T p.V130= | Silent (SNP) | VAF 182/507 reads (36%) | called by muse, mutect2, varscan2
- MAST1 | c.2607G>A p.K869= | Silent (SNP) | VAF 136/399 reads (34%) | called by muse, mutect2, varscan2
- MDP1 | c.249C>T p.L83= | Silent (SNP) | VAF 113/334 reads (34%) | catalogued as rs1478470477, COSV99164628; called by muse, mutect2, varscan2
- MEFV | c.699G>A p.L233= | Silent (SNP) | VAF 297/613 reads (48%) | called by muse, mutect2, varscan2
- MEGF8 | c.6444C>T p.G2148= (on ENST00000251268 / NM_001271938.2; = p.G2081= on NM_001410.3) | Silent (SNP) | VAF 205/515 reads (40%) | called by muse, mutect2, varscan2
- MGA | c.4368T>A p.L1456= | Silent (SNP) | VAF 112/183 reads (61%) | called by muse, mutect2, varscan2
- MGAM2 | c.3126G>A p.R1042= | Silent (SNP) | VAF 141/445 reads (32%) | called by muse, mutect2, varscan2
- MIGA1 | c.1041C>T p.S347= | Silent (SNP) | VAF 95/221 reads (43%) | called by muse, mutect2, varscan2
- MMP9 | c.2013C>T p.A671= | Silent (SNP) | VAF 90/275 reads (33%) | called by muse, mutect2, varscan2
- MROH2B | c.1794C>T p.F598= | Silent (SNP) | VAF 87/253 reads (34%) | catalogued as rs767542509, COSV68186012; called by muse, mutect2, varscan2
- MTNR1A | c.354C>T p.I118= | Silent (SNP) | VAF 122/340 reads (36%) | catalogued as rs750086653; called by muse, mutect2, varscan2
- MUC12 | c.2412C>T p.S804= (on ENST00000379442; = p.S661= on NM_001164462.1) | Silent (SNP) | VAF 267/699 reads (38%) | called by muse, mutect2, varscan2
- MUC16 | c.40152G>A p.K13384= | Silent (SNP) | VAF 71/181 reads (39%) | catalogued as rs1368455740, COSV66691308; called by muse, mutect2, varscan2
- MUC16 | c.37701G>A p.R12567= | Silent (SNP) | VAF 65/210 reads (31%) | catalogued as COSV67472513; called by muse, mutect2, varscan2
- MUC4 | c.2601C>T p.I867= | Silent (SNP) | VAF 124/517 reads (24%) | catalogued as rs539328231; called by muse, mutect2, varscan2
- MUCL3 | c.174C>T p.I58= | Silent (SNP) | VAF 180/518 reads (35%) | called by muse, mutect2, varscan2
- MYO15B | c.1557C>T p.S519= | Silent (SNP) | VAF 168/407 reads (41%) | catalogued as rs1372690659; called by muse, mutect2, varscan2
- MYPN | c.1416G>A p.G472= | Silent (SNP) | VAF 106/280 reads (38%) | catalogued as rs1342724141, COSV62731696; called by muse, mutect2, varscan2
- NACC1 | c.168G>A p.R56= | Silent (SNP) | VAF 161/466 reads (35%) | called by muse, mutect2, varscan2
- NCKAP1 | c.813G>A p.G271= | Silent (SNP) | VAF 128/325 reads (39%) | called by muse, mutect2, varscan2
- NCKAP1L | c.2713C>T p.L905= | Silent (SNP) | VAF 119/390 reads (31%) | called by muse, mutect2, varscan2
- NFE2 | c.939G>A p.G313= | Silent (SNP) | VAF 186/497 reads (37%) | called by muse, mutect2, varscan2
- NOTCH2 | c.6543C>T p.N2181= | Silent (SNP) | VAF 183/415 reads (44%) | catalogued as rs1457168283; called by muse, mutect2, varscan2
- NPAS3 | c.2019C>T p.I673= (on ENST00000356141 / NM_001164749.2; = p.I641= on NM_022123.3) | Silent (SNP) | VAF 200/520 reads (38%) | called by muse, mutect2, varscan2
- NRXN1 | c.4413G>A p.K1471= | Silent (SNP) | VAF 83/282 reads (29%) | catalogued as rs982854129, COSV100640878; called by muse, mutect2, varscan2
- NSUN4 | c.495T>G p.P165= | Silent (SNP) | VAF 102/373 reads (27%) | called by muse, mutect2, varscan2
- NTNG2 | c.825C>T p.F275= | Silent (SNP) | VAF 189/273 reads (69%) | called by muse, mutect2, varscan2
- OGDHL | c.2457C>T p.S819= | Silent (SNP) | VAF 111/323 reads (34%) | catalogued as COSV65101294; called by muse, mutect2, varscan2
- OR11H1 | c.267C>T p.F89= | Silent (SNP) | VAF 26/646 reads (4%) | catalogued as rs1488523509, COSV99421850; called by muse, mutect2
- OR2M5 | c.558C>T p.I186= | Silent (SNP) | VAF 128/667 reads (19%) | catalogued as rs769049492, COSV100822889; called by muse, mutect2, varscan2
- OR4C13 | c.180C>T p.F60= | Silent (SNP) | VAF 133/373 reads (36%) | catalogued as COSV73648804; called by muse, mutect2, varscan2
- OR4C3 | c.753C>T p.P251= | Silent (SNP) | VAF 117/368 reads (32%) | catalogued as rs267602917; called by muse, mutect2, varscan2
- OR4D2 | c.870G>A p.R290= | Silent (SNP) | VAF 144/453 reads (32%) | catalogued as COSV101613853, COSV73459698; called by muse, mutect2, varscan2
- OR51D1 | c.974G>A p.*325= | Silent (SNP) | VAF 62/167 reads (37%) | called by muse, mutect2, varscan2
- OR51E2 | c.885C>T p.T295= | Silent (SNP) | VAF 173/417 reads (41%) | called by muse, mutect2, varscan2
- OR56B4 | c.303C>T p.P101= | Silent (SNP) | VAF 162/469 reads (35%) | catalogued as COSV100337662, COSV57204364; called by muse, mutect2, varscan2
- OR5B2 | c.30C>T p.F10= | Silent (SNP) | VAF 86/241 reads (36%) | called by muse, mutect2, varscan2
- OR6F1 | c.300G>A p.Q100= | Silent (SNP) | VAF 59/447 reads (13%) | catalogued as rs752777776, COSV57467493; called by muse, mutect2, varscan2
- OR8D1 | c.747G>A p.V249= | Silent (SNP) | VAF 121/225 reads (54%) | catalogued as rs764462941; called by muse, mutect2, varscan2
- OTUD7B | c.2133C>T p.P711= | Silent (SNP) | VAF 486/665 reads (73%) | called by muse, mutect2, varscan2
- P2RY1 | c.504G>A p.A168= | Silent (SNP) | VAF 172/439 reads (39%) | called by muse, mutect2, varscan2
- PAPPA | c.1677C>T p.T559= | Silent (SNP) | VAF 211/299 reads (71%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1683C>T p.F561= | Silent (SNP) | VAF 212/1227 reads (17%) | catalogued as rs782576597, COSV50802007; called by muse, mutect2, varscan2
- PCDHGA2 | c.2358G>A p.E786= | Silent (SNP) | VAF 187/490 reads (38%) | catalogued as rs753009356; called by muse, mutect2, varscan2
- PCDHGA3 | c.1648C>T p.L550= | Silent (SNP) | VAF 215/555 reads (39%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.1584C>T p.F528= | Silent (SNP) | VAF 180/521 reads (35%) | called by muse, mutect2, varscan2
- PEX5 | c.708C>T p.G236= | Silent (SNP) | VAF 151/254 reads (59%) | catalogued as rs778009052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKFB1 | c.1212C>T p.F404= | Silent (SNP) | VAF 115/304 reads (38%) | catalogued as COSV100895635, COSV100895642; called by muse, mutect2, varscan2
- PFKL | c.1368C>T p.A456= | Silent (SNP) | VAF 123/326 reads (38%) | catalogued as rs142617054; called by muse, mutect2, varscan2
- PHYHIPL | c.354C>T p.V118= | Silent (SNP) | VAF 140/375 reads (37%) | catalogued as rs1198771587; called by muse, mutect2, varscan2
- PKD1L3 | c.2412G>A p.G804= | Silent (SNP) | VAF 180/535 reads (34%) | catalogued as rs949620605; called by muse, mutect2, varscan2
- PNLIP | c.675C>T p.P225= | Silent (SNP) | VAF 197/374 reads (53%) | catalogued as COSV65041524; called by muse, mutect2, varscan2
- PNLIPRP3 | c.168C>T p.F56= | Silent (SNP) | VAF 124/487 reads (25%) | called by muse, mutect2, varscan2
- PNPLA1 | c.30G>A p.P10= | Silent (SNP) | VAF 150/384 reads (39%) | catalogued as rs1014373591; called by muse, mutect2, varscan2
- PNPLA6 | c.1203T>A p.P401= (on ENST00000414982 / NM_001166111.2; = p.P353= on NM_006702.5) | Silent (SNP) | VAF 132/360 reads (37%) | called by muse, mutect2
- PPFIA3 | c.111G>T p.T37= | Silent (SNP) | VAF 184/485 reads (38%) | catalogued as COSV61952354; called by muse, mutect2, varscan2
- PPP1CC | c.951C>T p.I317= | Silent (SNP) | VAF 90/291 reads (31%) | called by muse, mutect2, varscan2
- PPP1R9B | c.2016G>A p.K672= | Silent (SNP) | VAF 141/323 reads (44%) | catalogued as rs369762042; called by muse, mutect2, varscan2
- PPTC7 | c.864G>A p.K288= | Silent (SNP) | VAF 103/326 reads (32%) | called by muse, mutect2, varscan2
- PRAMEF10 | c.1287C>T p.I429= | Silent (SNP) | VAF 81/243 reads (33%) | called by muse, mutect2, varscan2
- PRPF6 | c.1683C>T p.A561= | Silent (SNP) | VAF 111/279 reads (40%) | called by muse, mutect2, varscan2
- PRSS37 | c.204C>T p.F68= | Silent (SNP) | VAF 60/248 reads (24%) | called by muse, varscan2
- R3HDM1 | c.3063C>T p.P1021= | Silent (SNP) | VAF 160/467 reads (34%) | called by muse, mutect2, varscan2
- RABGGTB | c.87C>T p.S29= | Silent (SNP) | VAF 94/213 reads (44%) | called by muse, mutect2, varscan2
- RAD54L2 | c.2496G>A p.V832= | Silent (SNP) | VAF 175/464 reads (38%) | called by muse, mutect2, varscan2
- RANBP17 | c.3081G>A p.Q1027= | Silent (SNP) | VAF 79/225 reads (35%) | called by muse, mutect2, varscan2
- RBAK | c.1500C>T p.D500= | Silent (SNP) | VAF 127/646 reads (20%) | catalogued as COSV62332116; called by muse, mutect2, varscan2
- RBM39 | c.204C>T p.S68= | Silent (SNP) | VAF 150/447 reads (34%) | called by muse, mutect2, varscan2
- RBM5 | c.387G>A p.V129= | Silent (SNP) | VAF 105/307 reads (34%) | called by muse, mutect2, varscan2
- RCOR2 | c.1170G>A p.Q390= | Silent (SNP) | VAF 174/445 reads (39%) | called by muse, mutect2, varscan2
- REG3A | c.261C>T p.F87= | Silent (SNP) | VAF 140/433 reads (32%) | catalogued as rs774802444, COSV59409025; called by muse, mutect2, varscan2
- RESP18 | c.183C>T p.F61= | Silent (SNP) | VAF 159/437 reads (36%) | called by muse, mutect2, varscan2
- RYR1 | c.9948G>A p.L3316= | Silent (SNP) | VAF 181/472 reads (38%) | called by muse, mutect2, varscan2
- RYR2 | c.14076C>T p.S4692= | Silent (SNP) | VAF 50/516 reads (10%) | catalogued as rs1188569107; called by muse, mutect2
- S1PR1 | c.219C>T p.T73= | Silent (SNP) | VAF 146/311 reads (47%) | catalogued as rs759199162; called by muse, mutect2, varscan2
- SAE1 | c.378C>T p.F126= | Silent (SNP) | VAF 85/218 reads (39%) | catalogued as rs750739165, COSV99538178; called by muse, mutect2, varscan2
- SCAF1 | c.585C>T p.S195= | Silent (SNP) | VAF 55/172 reads (32%) | catalogued as rs1288900386; called by muse, varscan2
- SCPEP1 | c.213C>T p.V71= | Silent (SNP) | VAF 86/249 reads (35%) | called by muse, mutect2, varscan2
- SCRIB | c.4056G>A p.L1352= | Silent (SNP) | VAF 195/639 reads (31%) | called by muse, mutect2, varscan2
- SDR16C5 | c.885C>T p.I295= | Silent (SNP) | VAF 105/413 reads (25%) | called by muse, mutect2, varscan2
- SELENOI | c.252C>T p.H84= | Silent (SNP) | VAF 42/278 reads (15%) | catalogued as rs368706871; called by muse, varscan2
- SEMA3E | c.1398T>A p.I466= | Silent (SNP) | VAF 125/181 reads (69%) | called by muse, mutect2, varscan2
- SEMA3F | c.1749G>A p.R583= | Silent (SNP) | VAF 125/335 reads (37%) | called by muse, mutect2, varscan2
- SEMA3G | c.642C>T p.S214= | Silent (SNP) | VAF 86/292 reads (29%) | catalogued as rs1425265854; called by muse, varscan2
- SEMA5B | c.399C>T p.P133= | Silent (SNP) | VAF 158/394 reads (40%) | called by muse, mutect2, varscan2
- SEMA6C | c.945C>T p.L315= | Silent (SNP) | VAF 96/440 reads (22%) | called by muse, mutect2, varscan2
- SERPINB11 | c.213C>T p.F71= | Silent (SNP) | VAF 83/249 reads (33%) | called by muse, mutect2, varscan2
- SERPIND1 | c.1437C>T p.I479= | Silent (SNP) | VAF 155/440 reads (35%) | catalogued as COSV99300297; called by muse, mutect2, varscan2
- SERPINI1 | c.885C>T p.F295= | Silent (SNP) | VAF 80/190 reads (42%) | catalogued as COSV55513094; called by muse, mutect2, varscan2
- SFN | c.258G>A p.E86= | Silent (SNP) | VAF 112/442 reads (25%) | called by muse, mutect2, varscan2
- SH3BP2 | c.1374C>T p.F458= | Silent (SNP) | VAF 114/300 reads (38%) | catalogued as rs748346628; called by muse, mutect2, varscan2
- SHISAL1 | c.324C>T p.F108= | Silent (SNP) | VAF 121/448 reads (27%) | catalogued as rs775909681; called by muse, mutect2, varscan2
- SLC12A9 | c.1179C>T p.N393= | Silent (SNP) | VAF 311/396 reads (79%) | catalogued as rs768393256; called by muse, mutect2, varscan2
- SLC15A2 | c.921C>T p.I307= | Silent (SNP) | VAF 108/312 reads (35%) | called by muse, mutect2, varscan2
- SLC16A12 | c.270C>T p.I90= | Silent (SNP) | VAF 106/349 reads (30%) | called by muse, mutect2, varscan2
- SLC4A5 | c.489C>T p.F163= | Silent (SNP) | VAF 191/455 reads (42%) | catalogued as rs199820280; called by muse, mutect2, varscan2
- SLC6A11 | c.1434C>T p.F478= | Silent (SNP) | VAF 147/446 reads (33%) | catalogued as rs767702126, COSV54391133; called by muse, mutect2, varscan2
- SLC6A12 | c.159C>T p.I53= | Silent (SNP) | VAF 129/384 reads (34%) | called by muse, mutect2, varscan2
- SLC7A4 | c.744C>T p.F248= | Silent (SNP) | VAF 199/500 reads (40%) | catalogued as rs368179139; called by muse, mutect2, varscan2
- SLC8A3 | c.2232C>T p.A744= (on ENST00000381269 / NM_183002.3; = p.A742= on NM_033262.4) | Silent (SNP) | VAF 159/467 reads (34%) | catalogued as COSV53691597; called by muse, mutect2, varscan2
- SLCO3A1 | c.268C>T p.L90= | Silent (SNP) | VAF 168/270 reads (62%) | catalogued as COSV100575363; called by muse, mutect2, varscan2
- SMYD2 | c.837C>T p.I279= | Silent (SNP) | VAF 54/376 reads (14%) | called by muse, mutect2, varscan2
- SNAI3 | c.198C>T p.A66= | Silent (SNP) | VAF 227/671 reads (34%) | catalogued as rs71395313; called by muse, mutect2, varscan2
- SOX4 | c.444C>T p.S148= | Silent (SNP) | VAF 156/388 reads (40%) | catalogued as rs934149346; called by muse, varscan2
- SPANXN3 | c.330G>A p.K110= | Silent (SNP) | VAF 228/545 reads (42%) | called by muse, mutect2, varscan2
- SPATC1 | c.219C>T p.F73= | Silent (SNP) | VAF 123/259 reads (47%) | catalogued as COSV66299911; called by muse, mutect2, varscan2
- SPINT2 | c.243G>A p.K81= | Silent (SNP) | VAF 86/251 reads (34%) | catalogued as COSV56648600; called by muse, mutect2, varscan2
- STPG2 | c.1155T>A p.S385= | Silent (SNP) | VAF 138/365 reads (38%) | called by muse, mutect2, varscan2
- SYNPO2 | c.2427C>T p.A809= | Silent (SNP) | VAF 177/493 reads (36%) | catalogued as rs138266651; called by muse, mutect2, varscan2
- SZRD1 | c.306C>T p.I102= | Silent (SNP) | VAF 76/353 reads (22%) | catalogued as rs773822169; called by muse, mutect2, varscan2
- TARBP1 | c.1170C>T p.I390= | Silent (SNP) | VAF 125/414 reads (30%) | called by muse, mutect2, varscan2
- TAS2R60 | c.711C>T p.P237= | Silent (SNP) | VAF 230/503 reads (46%) | catalogued as COSV100223484, COSV60330743; called by muse, mutect2, varscan2
- TCIRG1 | c.2466C>T p.P822= | Silent (SNP) | VAF 123/299 reads (41%) | catalogued as rs1253231019; called by muse, mutect2, varscan2
- TDP2 | c.675C>T p.S225= | Silent (SNP) | VAF 97/243 reads (40%) | catalogued as COSV61968127; called by muse, mutect2, varscan2
- TDRD6 | c.843G>A p.E281= | Silent (SNP) | VAF 185/490 reads (38%) | called by muse, mutect2, varscan2
- TECPR1 | c.2820C>T p.I940= | Silent (SNP) | VAF 532/677 reads (79%) | called by muse, mutect2
- TENT5C | c.858G>A p.R286= | Silent (SNP) | VAF 73/345 reads (21%) | catalogued as rs1265299855, COSV65616088; called by muse, mutect2, varscan2
- TEX13C | c.2229G>A p.E743= | Silent (SNP) | VAF 161/516 reads (31%) | called by muse, mutect2, varscan2
- TF | c.1782G>A p.A594= | Silent (SNP) | VAF 174/467 reads (37%) | catalogued as rs778400078, COSV53917621; called by muse, mutect2, varscan2
- THSD7B | c.1098G>A p.R366= | Silent (SNP) | VAF 150/387 reads (39%) | catalogued as rs768450248, COSV55695889; called by muse, mutect2, varscan2
60 further variants in this file (0 protein-altering or splice-affecting, 26 silent, 34 other) are not listed here.
